Somatic mutation profile of tumor specimen TCGA-Y8-A8S0-01A (aliquot TCGA-Y8-A8S0-01A-11D-A36X-10) from TCGA case TCGA-Y8-A8S0, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 58.5 years (21,383 days).
Specimen TCGA-Y8-A8S0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf8764bf-15b3-4057-862d-d41053cdcaa8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Y8-A8S0-10A (Blood Derived Normal), aliquot TCGA-Y8-A8S0-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e787ac3c-1790-49e8-993b-0db56b05b695

The open-access MAF lists 42 somatic variants for this specimen: 32 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 8, Nonsense Mutation 2, Intron 1, Frame Shift Del 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.5404T>A p.Y1802N | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99565094; called by muse, mutect2, varscan2
- ADCY6 | c.284A>C p.E95A | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.214); catalogued as rs1186845166, COSV100326392; called by muse, mutect2, varscan2
- CD6 | c.90C>G p.S30R | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.289); catalogued as COSV100532783, COSV100533169; called by muse, mutect2, varscan2
- CPNE4 | c.1268C>A p.S423* | Nonsense Mutation (SNP) | VAF 56/133 reads (42%) | catalogued as COSV101456564; called by muse, mutect2, varscan2
- DDX46 | c.608A>G p.D203G | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV100844845; called by muse, mutect2
- DLEC1 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.199); catalogued as COSV100341404; called by muse, mutect2, varscan2
- DYNC2H1 | c.8459C>T p.P2820L | Missense Mutation (SNP) | VAF 784/1739 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV100517456; called by muse, mutect2, varscan2
- ERBIN | c.3168G>A p.M1056I | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV99395788; called by muse, mutect2, varscan2
- GAB4 | c.416A>G p.D139G | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV101271872; called by muse, mutect2, varscan2
- GTF3C2 | c.1676G>A p.S559N | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV53127804, COSV99272124; called by muse, mutect2
- HGSNAT | c.1402T>C p.Y468H | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.141); catalogued as COSV99925068; called by muse, mutect2, varscan2
- HSPB9 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV99863353; called by muse, mutect2, varscan2
- KCNU1 | c.1493C>A p.S498Y | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV67758257; called by muse, mutect2, varscan2
- LCE2C | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 75/148 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs755367389, COSV100909381; called by muse, mutect2, varscan2
- MCMBP | c.1024T>A p.S342T | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.053); catalogued as COSV100749994; called by muse, mutect2, varscan2
- METTL14 | c.401T>C p.I134T | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101183342; called by muse, mutect2, varscan2
- MRC1 | c.4220C>T p.A1407V | Missense Mutation (SNP) | VAF 214/426 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs1305039013; called by muse, mutect2, varscan2
- NEB | c.18662del p.G6221Efs*8 | Frame Shift Del (DEL) | VAF 39/86 reads (45%) | catalogued as COSV50818264; called by mutect2, pindel*, varscan2
- OLFML2B | c.129G>C p.E43D | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1430091369, COSV99667991; called by muse, mutect2, varscan2
- PI15 | c.642G>T p.K214N | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99477773; called by muse, mutect2, varscan2
- PI15 | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99477774; called by muse, mutect2, varscan2
- RBM17 | c.890C>G p.T297S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV101159022; called by muse, mutect2, varscan2
- RBP1 | c.362G>C p.R121T (on ENST00000619087 / NM_001365940.2; = p.R183T on NM_002899.5) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV99218633; called by muse, mutect2, varscan2
- RENBP | c.871T>C p.F291L | Missense Mutation (SNP) | VAF 148/156 reads (95%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV100892362; called by muse, mutect2, varscan2
- SLC16A12 | c.1076T>C p.M359T | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV100369984; called by muse, mutect2, varscan2
- SYCN | c.366G>A p.W122* | Nonsense Mutation (SNP) | VAF 56/129 reads (43%) | catalogued as rs1185550913, COSV100355720; called by muse, mutect2, varscan2
- TOGARAM1 | c.4988A>T p.N1663I | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV100817779; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1295G>A p.S432N | Missense Mutation (SNP) | VAF 72/135 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99534821; called by muse, mutect2, varscan2
- VWA7 | c.986A>C p.E329A | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV100989865; called by muse, mutect2, varscan2
- ZNRF4 | c.1237G>C p.E413Q | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs551914284, COSV55774306, COSV99706328; called by muse, mutect2, varscan2
- COL6A2 | c.1970-6_1970del p.X657_splice | Splice Site (DEL) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- IGLC3 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 20/154 reads (13%) | PolyPhen possibly damaging (0.902); called by mutect2, varscan2
- BOD1L1 | c.6462G>A p.L2154= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as COSV99238307; called by muse, mutect2, varscan2
- BTBD16 | c.870G>A p.Q290= | Silent (SNP) | VAF 53/110 reads (48%) | catalogued as COSV99584473; called by muse, mutect2, varscan2
- HBS1L | c.303A>G p.L101= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV100121957; called by muse, mutect2, varscan2
- MAOA | c.1428T>C p.P476= | Silent (SNP) | VAF 51/55 reads (93%) | catalogued as COSV100108589; called by muse, mutect2, varscan2
- PPP1R12B | c.1683C>G p.S561= | Silent (SNP) | VAF 43/119 reads (36%) | catalogued as COSV100406478; called by muse, mutect2, varscan2
- WAC | c.156T>A p.P52= | Silent (SNP) | VAF 86/183 reads (47%) | catalogued as COSV100610848; called by muse, mutect2, varscan2
- WDR19 | c.1995T>G p.A665= | Silent (SNP) | VAF 37/73 reads (51%) | catalogued as COSV99975162; called by muse, mutect2, varscan2
- ZNF536 | c.2997A>G p.A999= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs1458821897, COSV100834609; called by muse, mutect2, varscan2
- IGLL5 | chr22:22901078 C>T | 3'Flank (SNP) | VAF 152/645 reads (24%) | called by muse, mutect2, varscan2
- NVL | c.2183-6703A>G | Intron (SNP) | VAF 138/298 reads (46%) | catalogued as COSV99893637; called by muse, mutect2, varscan2
